Surgical pathology report (de-identified scan), TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-A7RC-06A (Metastatic).

[page 1 of 2]
Patient: [REDACTED]

Lung
Metastasis

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

100-0-3

carcinoma, squamous cell, NOS

Site: Lung, NOS C349 80743

CLINICAL HISTORY:

Squamous cell carcinoma of the esophagus.

lv 1/16/14

GROSS EXAMINATION:

A. "Right lower lobe wedge", received fresh for frozen section and placed in formalin at [REDACTED] is a 3.88 gram and 7 x 1.9 x 1 cm wedge of lung. The pleura is grossly unremarkable. The staple line is removed and the underlying surgical resection margin inked blue.

Sectioning demonstrates five distinct well-circumscribed firm white nodules. Nodule 1 (representative frozen as AF1) measures 0.7 x 0.3 x 0.3 cm and directly underlies the pleura. Nodule 2 measures 0.3 x 0.3 x 0.2 cm and directly underlies both the pleural surface and the resection margin. Nodule 3 measures 0.7 x 0.6 x 0.3 cm and directly underlies the pleural surface and the resection margin. Nodule 4 measures 0.3 x 0.3 x 0.3 cm and directly underlies the pleural surface opposite the resection margin. Nodule 5 measures 0.1 x 0.1 x 0.1 cm and directly underlies the pleural surface. The uninvolved parenchyma appears grossly unremarkable.

BLOCK SUMMARY:

- A1- representative nodule 1 (frozen remnant AF1)
- A2- representative nodule 2 (approximately 90%)
- A3- representative nodule 3 (approximately 80%)
- A4- representative nodule 4 (larger fragments, larger nodule, approximately 80%) and representative nodule 5 (smaller fragment, smaller nodule, approximately 90%)
- A5- representative uninvolved parenchyma

B. "Right upper lobe wedge", received fresh for frozen section and placed in formalin at [REDACTED] is a 3.95 gram and 6.2 x 1.9 x 1 cm wedge of lung. The pleural surface is grossly unremarkable. The staple line is removed and underlying resection margin is inked blue. Three discrete well-circumscribed firm white nodules are identified. Nodule 1 measures 0.5 x 0.4 x 0.4 cm and comes to within 0.1 cm of the nearest overlying pleural surface. A representative section of nodule 1 is submitted for frozen section as BF1. No remaining nodule 1 is identified in the fixed tissue. Nodule 2 measures 0.3 x 0.3 x 0.3 cm and comes to within 0.1 cm of the nearest pleural surface and 0.4 cm of the nearest resection margin. Nodule 3 measures 0.3 x 0.3 x 0.2 cm and directly underlies the pleural surface and comes to within 0.5 cm of the nearest resection margin. Nodule 4 measures 0.1 x 0.5 x 0.5 cm. The uninvolved lung parenchyma is grossly unremarkable.

BLOCK SUMMARY:

- B1- representative nodule 1 (frozen remnant BF1)
- B2- parenchyma adjacent to nodule
- B3- representative nodule 2 (approximately 50%)
- B4- representative nodule 3 (approximately 90%)
- B5- representative normal parenchyma and nodule 4.

slides to Dr.

INTRA OPERATIVE CONSULTATION:

A. "Right lower lobe wedge": AF1 (rep of nodule)-squamous cell carcinoma.

B. "Right upper lobe wedge": BF1 (rep of nodule)-squamous cell carcinoma

MICROSCOPIC EXAMINATION:

[REDACTED]

[page 2 of 2]
Microscopic examination is performed.

DIAGNOSIS:

A. RIGHT LOWER LOBE (WEDGE RESECTION):

LUNG TISSUE POSITIVE FOR MULTIPLE PLEURAL BASED SQUAMOUS CELL CARCINOMAS, MORPHOLOGICALLY CONSISTENT WITH METASTASIS FROM ESOPHAGEAL PRIMARY.

SEE COMMENT.

TUMOR SIZE: 5 NODULES - 0.1 TO 0.7 CM IN GREATEST DIMENSION.

OPERATIVE MARGIN: FREE OF TUMOR.

B. RIGHT UPPER LOBE (WEDGE RESECTION):

LUNG TISSUE POSITIVE FOR MULTIPLE PLEURAL BASED SQUAMOUS CELL CARCINOMAS, MORPHOLOGICALLY CONSISTENT WITH METASTASIS FROM ESOPHAGEAL PRIMARY.

SEE COMMENT.

TUMOR SIZE: 4 NODULES - 0.1 TO 0.5 CM IN GREATEST DIMENSION.

OPERATIVE MARGIN: FREE OF TUMOR.

ADDITIONAL FINDINGS: SMALL AIRWAYS DISEASE.

COMMENT: Per medical record, the patient has a history of squamous cell carcinoma of the esophagus. No pathology from the esophagus is available for review and comparison to the current case. The above tumor nodules are well circumscribed and peripherally located. This distribution and morphologic appearance favors metastatic squamous carcinoma.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]
Performed by: SURGICAL PATHOLOGY

Attending MD:

Ordering MD:

Consulting MDs:

met to primary esophageal case.

Criteria	Lung met	10/9/13	No

Source: NCI Genomic Data Commons file 46c078d7-5141-4fbb-9253-3f8d0957a3ca (TCGA-V5-A7RC.8D80B81B-B363-4971-AE00-E357FBC6AEF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).